CCDI case PBBKTT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9ff82abd-a619-49eb-991b-0601cc7578ca

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.7 years (4,623 days).

Biospecimens (2 samples)
- Sample 0DFJJ5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
